Somatic mutation profile of tumor specimen MMRF_1462_3_BM_CD138pos (aliquot MMRF_1462_3_BM_CD138pos_T1_KHS5U_L11093) from MMRF case MMRF_1462, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,779 days).
Specimen MMRF_1462_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c3aff0e-d2e7-4995-a99a-e5136567cc05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1462_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1462_1_PB_Whole_C3_KAS5U_L02464; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d65a80cd-7b1b-4b8d-8596-56649ca619e0

The open-access MAF lists 117 somatic variants for this specimen: 55 protein-altering or splice-affecting, 20 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 22, Silent 20, Intron 11, 5'UTR 6, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 2, 5'Flank 2, Translation Start Site 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 47/89 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1248958261, COSV50307674; called by muse, mutect2, varscan2
- ARG1 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as COSV51581477; called by muse, mutect2, varscan2
- ASNSD1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 146/294 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641119; called by muse, mutect2, varscan2
- ATE1 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs960328457; called by muse, mutect2, varscan2
- CDYL2 | c.596C>T p.T199I | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs372394862; called by muse, mutect2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- DNAH2 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 88/162 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs140417225; called by muse, mutect2, varscan2
- DSE | c.373A>G p.M125V | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1486246312; called by muse, mutect2, varscan2
- FAM71E2 | c.595G>T p.V199F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs771386874; called by muse, mutect2, varscan2
- IGKV5-2 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 74/77 reads (96%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760745682; called by muse, mutect2, varscan2
- IGKV5-2 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 87/89 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761508612; called by muse, mutect2, varscan2
- IGLL5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs767386322, COSV73250551; called by muse, mutect2, varscan2
- MARCHF3 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 93/154 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs760059259; called by muse, mutect2, varscan2
- MYO18A | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs887114321; called by muse, mutect2, varscan2
- NAXD | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 238/242 reads (98%) | catalogued as rs921496694, COSV57289297; called by muse, mutect2, varscan2
- PGBD5 | c.734C>T p.A245V (on ENST00000525115; = p.A314V on NM_001258311.2) | Missense Mutation (SNP) | VAF 148/250 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1488372662, COSV58413566; called by muse, mutect2, varscan2
- PPP1CA | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs771504128; called by muse, mutect2, varscan2
- PRRC2A | c.5560G>A p.D1854N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs1207990295; called by muse, mutect2
- UBQLN3 | c.1654A>T p.T552S | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs751495844; called by muse, mutect2
- ZNF142 | c.4631G>A p.R1544Q (on ENST00000411696 / NM_001379660.1; = p.R1344Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374554076; called by muse, varscan2
- ZNF43 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.795); catalogued as COSV61685227; called by muse, mutect2
- ACTG1 | c.101_115del p.I34_P38del | In Frame Del (DEL) | VAF 149/358 reads (42%) | called by mutect2, pindel, varscan2
- ANKRD16 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CFAP46 | c.4341C>G p.N1447K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CFH | c.3137C>A p.T1046N | Missense Mutation (SNP) | VAF 183/284 reads (64%) | SIFT tolerated (0.48); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CIT | c.4586C>G p.S1529C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COPA | c.283T>G p.Y95D | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COQ10A | c.44_65del p.A15Gfs*23 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- CRYGD | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DDIT4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAI4 | c.530+2T>G p.X177_splice | Splice Site (SNP) | VAF 40/40 reads (100%) | called by muse, mutect2, varscan2
- FBXL12 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FGD6 | c.554A>T p.D185V | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- GADD45A | c.146+2T>A p.X49_splice | Splice Site (SNP) | VAF 42/43 reads (98%) | called by muse, mutect2, varscan2
- GPR158 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 72/138 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- IGHV2-70D | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 60/80 reads (75%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, varscan2
- KHDRBS1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 50/234 reads (21%) | called by muse, mutect2, varscan2
- NLN | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NUMA1 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR1S2 | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.146); called by muse, mutect2
- PRRC2A | c.691C>G p.P231A | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2
- PSG11 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 82/163 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD21L1 | c.1486T>A p.S496T | Missense Mutation (SNP) | VAF 67/125 reads (54%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RB1CC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC35G2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 171/377 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYDE1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCIRG1 | c.2374G>C p.E792Q | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TPH2 | c.423T>G p.I141M | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- TTN | c.17105A>C p.Q5702P (on ENST00000591111; = p.Q4775P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/83 reads (46%) | PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNF142 | c.4199_4209del p.H1400Lfs*3 (on ENST00000411696 / NM_001379660.1; = p.H1200Lfs*3 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by mutect2, pindel, varscan2
- ZNF727 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 71/145 reads (49%) | called by muse, mutect2, varscan2
- ZNF865 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CCDC62 | c.1446G>C p.L482= | Silent (SNP) | VAF 57/104 reads (55%) | called by muse, mutect2, varscan2
- CEP250 | c.721C>A p.R241= | Silent (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- DDIT4 | c.369G>A p.L123= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs1564804769; called by muse, mutect2, varscan2
- DISP3 | c.1639C>T p.L547= | Silent (SNP) | VAF 219/318 reads (69%) | catalogued as COSV53822452; called by muse, mutect2, varscan2
- ESYT3 | c.255C>T p.A85= | Silent (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- FREM2 | c.6990G>A p.V2330= | Silent (SNP) | VAF 81/92 reads (88%) | called by muse, mutect2, varscan2
- HSPA8 | c.441A>C p.P147= | Silent (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- IGLL5 | c.153C>T p.D51= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as rs759339896, COSV104440311, COSV73249815; called by muse, varscan2
- KHDRBS1 | c.561G>C p.L187= | Silent (SNP) | VAF 49/234 reads (21%) | called by muse, mutect2, varscan2
- MMP2 | c.345C>T p.R115= | Silent (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- NYAP1 | c.750C>T p.A250= | Silent (SNP) | VAF 78/158 reads (49%) | catalogued as rs147915491; called by muse, mutect2, varscan2
- OCA2 | c.786C>T p.S262= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV62353397; called by muse, mutect2
- PCDHA3 | c.1929G>A p.P643= | Silent (SNP) | VAF 20/159 reads (13%) | catalogued as rs924510716; called by muse, mutect2, varscan2
- PHF12 | c.2067C>T p.F689= | Silent (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- PUM1 | c.3207A>C p.V1069= | Silent (SNP) | VAF 81/136 reads (60%) | called by muse, mutect2, varscan2
- PUM1 | c.3111A>G p.V1037= | Silent (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2535C>G p.L845= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV53738858; called by muse, mutect2
- TOPORS | c.1815G>A p.Q605= | Silent (SNP) | VAF 145/326 reads (44%) | called by muse, mutect2, varscan2
- UMAD1 | c.15C>T p.F5= | Silent (SNP) | VAF 114/230 reads (50%) | called by muse, mutect2, varscan2
- ZNF142 | c.3786C>A p.P1262= (on ENST00000411696 / NM_001379660.1; = p.P1062= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- ABHD13 | c.*3876G>A | 3'UTR (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- ARL5B | c.*2893A>T | 3'UTR (SNP) | VAF 33/77 reads (43%) | called by muse, mutect2, varscan2
- BOLL | c.-16+235G>T | Intron (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.403+151C>A | Intron (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- COL3A1 | c.*220T>C | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- CYSLTR2 | c.*851G>T | 3'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- DECR1 | c.*187C>T | 3'UTR (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552578 G>A | 3'Flank (SNP) | VAF 46/48 reads (96%) | called by muse, mutect2, varscan2
- EIF3H | c.*431C>A | 3'UTR (SNP) | VAF 14/31 reads (45%) | catalogued as rs1164480684; called by muse, mutect2, varscan2
- ELP1 | c.741-16_741-11del | Intron (DEL) | VAF 45/131 reads (34%) | called by mutect2, pindel, varscan2
- FAM76B | c.*1297T>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- GABRB1 | c.240+248G>T | Intron (SNP) | VAF 10/182 reads (5%) | called by muse, mutect2
- HES1 | c.205-73G>C | Intron (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- IRAG1 | c.*1917T>C | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*2231C>T | 3'UTR (SNP) | VAF 41/77 reads (53%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1158A>T | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1036T>C | 3'UTR (SNP) | VAF 33/60 reads (55%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851175 T>C | 5'Flank (SNP) | VAF 134/250 reads (54%) | catalogued as rs529449665; called by muse, mutect2, varscan2
- MPIG6B | c.622-31C>A | Intron (SNP) | VAF 153/294 reads (52%) | called by muse, mutect2, varscan2
- MSRB3 | c.*2899A>T | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- NAALADL2 | c.-4T>G | 5'UTR (SNP) | VAF 165/343 reads (48%) | called by muse, mutect2, varscan2
- NCBP2 | c.*580G>C | 3'UTR (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- NFASC | c.*3140A>T | 3'UTR (SNP) | VAF 80/132 reads (61%) | called by muse, mutect2, varscan2
- PHKB | c.*1751A>G | 3'UTR (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- PIGG | c.-74G>A | 5'UTR (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- PLA2G4C | c.1006+135T>C | Intron (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- POLD4 | c.-91T>C | 5'UTR (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- PRLR | c.*5757C>T | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, mutect2, varscan2
- RNF144A | c.*3462G>C | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, mutect2, varscan2
- ROBO2 | c.-618G>T | 5'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- SAG | c.806+137C>T | Intron (SNP) | VAF 10/23 reads (43%) | catalogued as rs573374394; called by muse, mutect2, varscan2
- SEMA3D | c.*2934T>C | 3'UTR (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+2056G>A | Intron (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- SIX4 | c.*1582A>C | 3'UTR (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2883+58C>T | Intron (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2, varscan2
- SMAD7 | c.*487C>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as rs945462191; called by muse, mutect2, varscan2
- SRPK2 | c.71+82084A>T | Intron (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- TBXT | c.-75C>T | 5'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- TCTEX1D2 | chr3:196318331 del GAACTGGTCGC | 5'Flank (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- TMEM216 | c.*300C>T | 3'UTR (SNP) | VAF 147/319 reads (46%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.-139T>C | 5'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2
- ZCCHC10 | c.*305A>G | 3'UTR (SNP) | VAF 174/291 reads (60%) | called by muse, mutect2, varscan2
